Somatic mutation profile of tumor specimen MMRF_2422_1_BM_CD138pos (aliquot MMRF_2422_1_BM_CD138pos_T1_KHS5U_L11069) from MMRF case MMRF_2422, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,888 days).
Specimen MMRF_2422_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8bc17d-343e-4ed4-8a56-621d4c63bd55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2422_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2422_1_PB_Whole_C3_KHS5U_L11070; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faa58f5a-4e4a-4f54-bc3a-9c0f46906093

The open-access MAF lists 106 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 25, Silent 16, Intron 9, 5'UTR 9, 3'Flank 5, 5'Flank 4, RNA 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP61 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs567725378; called by muse, mutect2, varscan2
- CRISP3 | c.492C>A p.N164K (on ENST00000371159 / NM_001368123.1; = p.N146K on NM_006061.4) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV53819181; called by muse, mutect2, varscan2
- DRD5 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200733038, COSV58577265, COSV58580668; called by muse, mutect2, varscan2
- FREM2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1480479280, COSV54842656; called by muse, mutect2, varscan2
- IGKV4-1 | c.350A>C p.Y117S | Missense Mutation (SNP) | VAF 64/66 reads (97%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs371099186; called by muse, mutect2, varscan2
- KPNA2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs374149935; called by muse, mutect2
- NYNRIN | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs746599929, COSV66845654; called by muse, mutect2, varscan2
- PCLO | c.14479G>T p.E4827* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV61633669; called by muse, mutect2, varscan2
- PLD1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434314217, COSV60566110, COSV60571560; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2666A>G p.H889R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV51481823; called by muse, varscan2
- SCLT1 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1481337872, COSV55408124; called by muse, mutect2, varscan2
- SP8 | c.1195C>T p.R399C (on ENST00000361443 / NM_198956.4; = p.R417C on NM_182700.6) | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63866302; called by muse, mutect2, varscan2
- ZNHIT2 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs766332238; called by muse, mutect2, varscan2
- ABCA3 | c.4558A>T p.K1520* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- ACVR2B | c.613_641del p.W205Sfs*16 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | called by mutect2, pindel
- AMBN | c.801C>G p.G267= | Splice Region (SNP) | VAF 29/57 reads (51%) | called by mutect2, varscan2
- ANXA7 | c.1048T>A p.Y350N (on ENST00000372919 / NM_001320880.2; = p.Y328N on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1E | c.3887A>G p.Y1296C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLG5 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- DUSP2 | c.707T>G p.F236C | Missense Mutation (SNP) | VAF 149/440 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GCM1 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LIPJ | c.89A>T p.Y30F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRCH2 | c.1734T>A p.N578K | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.46); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LRRFIP1 | c.1312G>A p.V438M (on ENST00000392000 / NM_001137552.2; = p.V414M on NM_004735.4) | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LTBP1 | c.2363G>T p.R788L (on ENST00000404816 / NM_206943.4; = p.R462L on NM_000627.4) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MED23 | c.3420G>T p.E1140D | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.019); called by muse, mutect2
- METTL8 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV2 | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFPL3 | c.903G>C p.L301F (on ENST00000249007 / NM_001098535.1; = p.L272F on NM_006604.2) | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2
- SLC9C1 | c.1924A>C p.S642R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEF2 | c.5238A>G p.I1746M | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SULF1 | c.146T>A p.L49H | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SYNPO | c.2192G>A p.R731H (on ENST00000394243 / NM_001166208.2; = p.R487H on NM_007286.6) | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TINF2 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2
- CACNA1D | c.3021C>T p.C1007= (on ENST00000350061 / NM_001128840.3; = p.C1027= on NM_000720.4) | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs770555402, COSV55457912; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK11A | c.1659G>T p.T553= (on ENST00000378633 / NM_001313896.2; = p.T550= on NM_024011.4) | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- EVI2A | c.540T>C p.N180= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs535998011; called by muse, mutect2, varscan2
- FES | c.1569T>C p.I523= | Silent (SNP) | VAF 216/332 reads (65%) | called by muse, mutect2, varscan2
- GJD2 | c.642G>A p.L214= | Silent (SNP) | VAF 133/227 reads (59%) | catalogued as COSV51747599, COSV99290596; called by muse, mutect2, varscan2
- IGKV1D-8 | c.219A>T p.A73= | Silent (SNP) | VAF 134/222 reads (60%) | called by muse, mutect2, varscan2
- KIAA0232 | c.4017T>A p.S1339= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- KIF2B | c.1668G>T p.P556= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs902289645; called by muse, mutect2
- NRG4 | c.201A>T p.A67= | Silent (SNP) | VAF 90/277 reads (32%) | called by muse, varscan2
- OTOG | c.756C>T p.I252= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs1334832623; called by muse, mutect2, varscan2
- PTBP3 | c.681T>C p.A227= | Silent (SNP) | VAF 55/94 reads (59%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.1173C>T p.I391= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV51490475; called by muse, mutect2, varscan2
- TAS2R16 | c.859C>T p.L287= | Silent (SNP) | VAF 140/410 reads (34%) | called by muse, mutect2, varscan2
- TPO | c.1062G>A p.A354= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1209623772, COSV61110228; called by muse, mutect2
- TYRP1 | c.762G>A p.G254= | Silent (SNP) | VAF 105/358 reads (29%) | called by muse, mutect2, varscan2
- ZYG11A | c.2151T>C p.L717= | Silent (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2, varscan2
- AC008592.1 | chr5:95858883 T>G | 5'Flank (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.*707G>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- ANAPC7 | c.*134G>A | 3'UTR (SNP) | VAF 9/134 reads (7%) | catalogued as rs944383629; called by muse, mutect2
- ANKRD40 | c.-200C>T | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ARHGAP32 | c.*1966T>C | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- ARID2 | chr12:45727538 A>C | 5'Flank (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- ATAD3C | c.*1244G>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | catalogued as rs369946109; called by muse, mutect2
- BCL7C | chr16:30894341 G>A | 5'Flank (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- BMF | c.*1056C>T | 3'UTR (SNP) | VAF 71/96 reads (74%) | called by muse, mutect2, varscan2
- BMP6 | c.*1160_*1188del | 3'UTR (DEL) | VAF 30/210 reads (14%) | called by mutect2, pindel
- CACNG2 | c.-495G>A | 5'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- CARMIL1 | c.-285C>T | 5'UTR (SNP) | VAF 7/30 reads (23%) | catalogued as rs1168839751; called by muse, varscan2
- CCR7 | c.*251T>C | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- CD28 | c.*794T>G | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- COX15 | c.*1065C>T | 3'UTR (SNP) | VAF 26/544 reads (5%) | catalogued as rs1220898219; called by muse, mutect2
- DECR2 | c.662-10T>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- DTX1 | c.-433C>G | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57495151, COSV57497550; called by muse, mutect2, varscan2
- GCSAM | c.*475C>T | 3'UTR (SNP) | VAF 30/105 reads (29%) | catalogued as rs1183950385; called by muse, mutect2, varscan2
- GLRA3 | c.*1250A>T | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- GMEB1 | chr1:28718664 C>A | 3'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- GSTM2P1 | n.530C>T | RNA (SNP) | VAF 116/189 reads (61%) | called by muse, mutect2, varscan2
- HCFC1 | c.-151T>G | 5'UTR (SNP) | VAF 103/107 reads (96%) | catalogued as rs1367536201; called by muse, mutect2, varscan2
- HEPHL1 | c.*343T>G | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- INHBB | c.*68G>A | 3'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as rs889993617, COSV99736109; called by muse, mutect2, varscan2
- KLHL1 | c.-259C>T | 5'UTR (SNP) | VAF 76/151 reads (50%) | called by muse, mutect2, varscan2
- KPNA4 | c.*4370dup | 3'UTR (INS) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- KRT77 | c.*398T>G | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- LPAL2 | n.620A>C | RNA (SNP) | VAF 28/124 reads (23%) | called by muse, varscan2
- MICAL2 | c.2848-38C>T | Intron (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- MIR30C2 | chr6:71377130 A>G | 5'Flank (SNP) | VAF 10/41 reads (24%) | catalogued as rs997220929; called by muse, mutect2, varscan2
- MKI67 | c.-57C>G | 5'UTR (SNP) | VAF 50/221 reads (23%) | catalogued as rs1355653679; called by muse, mutect2, varscan2
- MTARC1 | c.-14C>T | 5'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as rs1307893913; called by muse, mutect2, varscan2
- MTUS1 | c.2449+148C>T | Intron (SNP) | VAF 88/90 reads (98%) | called by muse, mutect2, varscan2
- NETO2 | c.*1490A>G | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67103G>C | Intron (SNP) | VAF 107/328 reads (33%) | called by muse, mutect2, varscan2
- PIKFYVE | c.*2511T>A | 3'UTR (SNP) | VAF 64/99 reads (65%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-511G>T | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- RFPL3 | chr22:32362838 G>C | 3'Flank (SNP) | VAF 25/72 reads (35%) | called by muse, varscan2
- RFPL3 | chr22:32362980 G>T | 3'Flank (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- RNF183 | c.-38+373C>T | Intron (SNP) | VAF 54/153 reads (35%) | catalogued as rs756357941; called by muse, mutect2, varscan2
- RNF220 | c.*317C>G | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SGTA | c.827+47_827+49dup | Intron (INS) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- SLC45A3 | c.*332T>C | 3'UTR (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- SLC5A6 | c.*393C>G | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- SLC6A15 | c.-50G>A | 5'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- SMAD2 | c.*822C>T | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*148A>T | 3'UTR (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- TMEM132B | c.*1930G>A | 3'UTR (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- TSNARE1 | c.1446+4161G>A | Intron (SNP) | VAF 33/61 reads (54%) | catalogued as rs1446362475; called by muse, mutect2, varscan2
- UBXN2A | c.*4061G>T | 3'UTR (SNP) | VAF 129/449 reads (29%) | called by muse, mutect2, varscan2
- XIST | n.8904A>T | RNA (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- YWHAG | c.*1462G>C | 3'UTR (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- ZNF326 | c.209+763_209+768dup | Intron (INS) | VAF 24/62 reads (39%) | called by mutect2, varscan2
- ZNF713 | chr7:55941144 C>G | 3'Flank (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- ZNF713 | chr7:55942000 C>G | 3'Flank (SNP) | VAF 17/90 reads (19%) | called by muse, varscan2
